Gene-level copy-number profile of tumor specimen C3N-02582-01 (profiled together with C3N-02582-02) from CPTAC case C3N-02582, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 77.3 years (28,227 days).
Specimen C3N-02582-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7a9e124e-1288-4735-9a69-0e07b6a63c73.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02582-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/4cc6897c-1ec6-439d-90b1-db0204cb7b89

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 788; copy number 1: 27,759; copy number 2: 25,318; copy number 3: 4,115; copy number 4: 752; copy number 5: 107; copy number 6: 32; copy number 7: 38.

Homozygous deletions (total copy number 0; autosomes only): 787 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:93,811,825–113,433,555, 243 genes (broad region; genes not listed).
- chr6:145,382,535–158,822,252, 224 genes (broad region; genes not listed).
- chr8:64,091–12,665,588, 320 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 5,042 genes in 49 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,462,029–119,473,803, 2 genes, copy number 3: GAPDHP23, HSD3BP1.
- chr3:130,034,553–130,055,920, 2 genes, copy number 3: OR7E21P, AC083906.4.
- chr4:49,486,926–49,589,529, 12 genes, copy number 3–4: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:58,198–41,968,366, 620 genes, copy number 3 (broad region; genes not listed).
- chr5:80,288,449–81,751,797, 33 genes, copy number 3: KRT18P45, AC026410.1, AC026410.4, AC026410.2, SPZ1, RBMX2P5, AC026410.3, HNRNPA1P12, RNU6-211P, ZFYVE16, AC008771.1, FAM151B, RPS27AP9, RPL7P24, ANKRD34B, DBIP2, LINC01337, DHFR, AC008434.1, MTRNR2L2, MSH3, AC022493.2, AC022493.1, RASGRF2-AS1, RASGRF2, AC026427.2, AC026427.1, CKMT2-AS1, CKMT2, AC026436.1, ZCCHC9, ACOT12, SSBP2.
- chr5:82,545,862–91,612,566, 110 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr5:164,119,098–167,119,585, 17 genes, copy number 3: AC008662.1, AC008662.2, AC109466.1, LINC02143, AC008446.1, RNU6-209P, AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947, AC091819.2.
- chr5:169,552,449–176,345,991, 134 genes, copy number 4–6 (broad region; genes not listed).
- chr6:120,781,220–129,516,566, 91 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr6:130,827,406–144,853,034, 238 genes, copy number 3–7 (broad region; genes not listed).
- chr6:165,117,195–168,375,355, 73 genes, copy number 3 (broad region; genes not listed).
- chr6:170,535,120–170,738,536, 8 genes, copy number 3: PSMB1, TBP, PDCD2, AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr7:37,032–46,145,688, 814 genes, copy number 3–4 (broad region; genes not listed).
- chr7:46,476,457–55,878,164, 117 genes, copy number 4–6 (broad region; genes not listed).
- chr7:92,198,969–92,836,573, 18 genes, copy number 3 (within-gene range 2–3): KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P.
- chr8:69,110,513–75,352,327, 112 genes, copy number 3–4 (broad region; genes not listed).
- chr8:76,162,119–76,913,399, 11 genes, copy number 3: AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1.
- chr8:78,148,101–79,314,951, 12 genes, copy number 3: AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1.
- chr8:90,791,741–106,060,524, 296 genes, copy number 3–4 (broad region; genes not listed).
- chr8:107,899,316–111,757,710, 39 genes, copy number 3: RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7.
- chr8:119,862,662–130,017,129, 156 genes, copy number 3–5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:134,477,788–134,713,049, 5 genes, copy number 4 (within-gene range 1–4): ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3.
- chr8:134,722,947–138,497,261, 23 genes, copy number 3: AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, RNU6-144P, ZYXP1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B.
- chr8:143,816,344–145,066,685, 85 genes, copy number 4 (broad region; genes not listed).
- chr10:42,149,310–43,267,065, 34 genes, copy number 3: KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1, CCNYL2, AL391099.1, LINC00839, ZNF37BP, FXYD6P1, EIF3LP2, ZNF33B, AL022345.3, AL022345.1, AL022345.2, RNU6-1170P, AL022345.4, LINC01518, VN1R54P, CUBNP1, LINC02632, RSU1P1, DUXAP3, AL022344.1, BMS1, RNU6-885P, LINC02623, LINC01264, MIR5100, RET, AC010864.1, CSGALNACT2, RASGEF1A.
- chr11:21,000,881–25,926,808, 40 genes, copy number 3: RNA5SP336, AC090857.1, AC090857.2, AC099730.1, RNA5SP337, ANO5, AC116534.1, AC107882.1, AC107886.1, AC104009.1, SLC17A6, AC040936.1, LINC01495, AC055878.1, FANCF, GAS2, RNA5SP338, SVIP, AC006299.1, CCDC179, LINC02718, AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1, LINC02726, AC100768.1, RNU6-783P, AC099842.1, LINC02686, Y_RNA, LUZP2, AC115990.1, AC087373.1, RPL36AP40, AC100770.1, LINC02699, AC013799.1.
- chr11:66,546,395–80,957,634, 438 genes, copy number 3 (broad region; genes not listed).
- chr11:81,821,272–83,423,516, 35 genes, copy number 3: MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr11:100,336,856–105,531,697, 83 genes, copy number 3 (broad region; genes not listed).
- chr12:12,310–991,190, 28 genes, copy number 4 (within-gene range 1–4): DDX11L8, WASH8P, FAM138D, IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1.
- chr12:30,926,428–32,007,435, 47 genes, copy number 3: TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1.
- chr12:39,293,228–41,072,415, 20 genes, copy number 3–4: KIF21A, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1.
- chr14:43,274,824–47,675,605, 44 genes, copy number 3: TUBBP3, HNRNPUP1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L, MDGA2, AL359951.1, RPA2P1, RPL13AP2, RPS15AP3.
- chr14:57,563,920–64,226,433, 120 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr16:1,221,651–18,201,956, 574 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr16:19,476,916–20,925,006, 43 genes, copy number 3: AC130456.3, RNU4-46P, AC130456.5, GDE1, AC130456.6, CCP110, VPS35L, AC002550.2, KNOP1, AC002550.1, IQCK, AC027130.1, LARP7P2, GPRC5B, GPR139, AC092132.2, AC092132.1, SNRPEP3, GP2, UMOD, PDILT, AC106796.1, ACSM5, AC137056.1, ACSM2A, AC137056.2, ACSM2B, AC141273.1, ACSM5P1, ACSM3, AC141273.3, AC141273.2, ACSM1, THUMPD1, AC004381.3, AC004381.4, AC004381.1, ERI2, RNU6-944P, REXO5, AC004381.2, DCUN1D3, LYRM1.
- chr17:36,861,674–40,721,932, 159 genes, copy number 3 (broad region; genes not listed).
- chr17:69,244,311–71,621,436, 24 genes, copy number 3 (within-gene range 2–3): ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5.
- chr17:74,670,077–75,785,893, 63 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr21:33,481,580–44,262,216, 252 genes, copy number 3 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 25,973. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
